FM case AD14299 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Uterus, NOS.
https://portal.gdc.cancer.gov/cases/8e7bbe9c-7c89-4b64-9ceb-4815e6321be3

Female, 59.3 years: Carcinosarcoma, NOS (ICD-O-3 8980/3) of the uterus; metastasis biopsied or resected from the endometrium. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
